Somatic mutation profile of tumor specimen ALCH-B01Y-TTP1-A (aliquot ALCH-B01Y-TTP1-A-2-0-D-A679-36) from ALCHEMIST case ALCH-B01Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,894 days).
Specimen ALCH-B01Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62ccda36-bc6e-424c-b782-7201467bcc37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01Y-NB1-A (Blood Derived Normal), aliquot ALCH-B01Y-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18e93b82-3e85-479a-81b7-696af376f8d8

The open-access MAF lists 123 somatic variants for this specimen: 81 protein-altering or splice-affecting, 25 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 25, Intron 11, Nonsense Mutation 6, Splice Site 5, RNA 3, 3'Flank 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/601 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.291-1G>T p.X97_splice | Splice Site (SNP) | VAF 18/145 reads (12%) | hotspot (GDC flag); catalogued as rs112675807, CS004815, CS147061, CS982372, COSV58820323; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4637A>T p.N1546I | Missense Mutation (SNP) | VAF 40/693 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV57334087; called by muse, mutect2
- ARMH3 | c.1393A>G p.M465V | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1169828777, COSV64234397; called by muse, mutect2
- ATP8B4 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 29/414 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.491); catalogued as COSV52711717; called by muse, mutect2
- CACNA1E | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV62405927, COSV62425336; called by muse, mutect2, varscan2
- CD4 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.435); catalogued as rs373415505; called by muse, mutect2
- CFHR4 | c.733C>A p.L245I (on ENST00000367416 / NM_001201551.2; = p.L246I on NM_001201550.3) | Missense Mutation (SNP) | VAF 40/781 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs745610475; called by muse, mutect2
- DOCK2 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 18/413 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1046162059, COSV56992193; called by muse, mutect2
- INSC | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs1160165973, COSV65410990; called by muse, mutect2
- LRP1 | c.3772G>A p.G1258S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs138433565; called by muse, mutect2
- MSH4 | c.2420T>C p.V807A | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as rs772856906; called by muse, mutect2, varscan2
- MYO9A | c.4921A>G p.I1641V | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1024479914; called by muse, mutect2
- OR8H3 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100538969; called by muse, mutect2
- PCDH8 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs373933829, COSV100131644; called by muse, mutect2, varscan2
- POTEF | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 36/684 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); catalogued as rs755975114, COSV62541232; called by muse, mutect2
- PRRC1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99031353; called by muse, mutect2
- RBM10 | c.724+1G>T p.X242_splice | Splice Site (SNP) | VAF 58/320 reads (18%) | catalogued as COSV61309829, COSV61312898, COSV61313630; called by muse, mutect2, varscan2
- SEMA5A | c.1595G>T p.C532F | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104429806; called by muse, mutect2
- SHH | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 50/727 reads (7%) | catalogued as COSV51920393; called by muse, mutect2
- SV2A | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 48/594 reads (8%) | catalogued as COSV64966160; called by muse, mutect2
- TAAR5 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.23); catalogued as rs1418454086, COSV57798962; called by muse, mutect2, varscan2
- VWC2L | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV56965792; called by muse, mutect2
- ZNF804A | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs1357450329; called by muse, mutect2, varscan2
- ZNF804B | c.2885C>A p.P962Q | Missense Mutation (SNP) | VAF 31/503 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60821701, COSV60826402; called by muse, mutect2
- ZNF99 | c.129G>T p.L43= | Splice Region (SNP) | VAF 10/220 reads (5%) | catalogued as COSV68056209, COSV99078016; called by muse, mutect2
- ADAMTS13 | c.1584+1G>T p.X528_splice | Splice Site (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- ALDH4A1 | c.1045T>A p.S349T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ARHGAP11B | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 49/720 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- ASL | c.208-2A>C p.X70_splice | Splice Site (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- BBS10 | c.1636A>C p.T546P | Missense Mutation (SNP) | VAF 34/567 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- BMS1 | c.2471A>T p.K824M | Missense Mutation (SNP) | VAF 30/644 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- C9orf131 | c.2168T>C p.V723A | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); called by muse, mutect2
- CAPN2 | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2
- CCR10 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- CD200R1 | c.923T>A p.V308E (on ENST00000471858 / NM_170780.3; = p.V331E on NM_138806.4) | Missense Mutation (SNP) | VAF 24/585 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- CES5A | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.42); called by muse, mutect2
- CFAP43 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2
- CFAP43 | c.927G>T p.L309F | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- CHRM2 | c.361A>T p.R121W | Missense Mutation (SNP) | VAF 48/850 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL12A1 | c.5189A>G p.D1730G | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COP1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 22/482 reads (5%) | called by muse, mutect2
- COQ10A | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CRIPT | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2
- CYLC1 | c.1673T>G p.I558S | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DMD | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDC4 | c.1595T>G p.V532G | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- ERC2 | c.2141A>T p.Y714F | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2
- ETF1 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 29/405 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBN1 | c.2262T>A p.Y754* | Nonsense Mutation (SNP) | VAF 50/1050 reads (5%) | called by muse, mutect2
- FBRS | c.884G>T p.R295L (on ENST00000287468; = p.R815L on NM_001105079.3) | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.399); called by muse, mutect2
- FRG2C | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 47/1317 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- GLDC | c.1855G>T p.A619S | Missense Mutation (SNP) | VAF 31/719 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.936); called by muse, mutect2
- GPR87 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGFN1 | c.1807G>A p.D603N (on ENST00000295591 / NM_001367841.1; = p.D3060N on NM_001164586.2) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ITPRID2 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 43/446 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); called by muse, mutect2
- KDM5D | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIF2B | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- KLHL4 | c.1898G>T p.C633F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.37); called by muse, mutect2
- LRP1B | c.2810G>T p.G937V | Missense Mutation (SNP) | VAF 34/551 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- MS4A10 | c.761T>A p.I254K | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2
- MXRA5 | c.8301G>C p.W2767C | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC1 | c.1024T>G p.W342G | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NRAP | c.2286T>A p.Y762* (on ENST00000359988 / NM_001322945.2; = p.Y727* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 14/361 reads (4%) | called by muse, mutect2
- OR1L8 | c.596T>A p.V199E | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- OR2T34 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PKD2 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 24/796 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- PSD2 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2
- RAB3GAP1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 52/601 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- RAPH1 | c.3137T>A p.V1046E | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- RUNX1T1 | c.1586G>A p.C529Y (on ENST00000265814 / NM_001198628.1; = p.C502Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SALL3 | c.3038G>A p.G1013E | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- SCN3A | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 48/898 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2
- SLC6A20 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- SLITRK4 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SMG1 | c.4318C>A p.L1440I | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- TNFRSF1A | c.739+1G>T p.X247_splice | Splice Site (SNP) | VAF 34/344 reads (10%) | called by muse, mutect2
- TRAV19 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- TTLL4 | c.2045A>G p.Q682R | Missense Mutation (SNP) | VAF 32/353 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2
- ZNF175 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 38/645 reads (6%) | called by muse, mutect2
- ZNF729 | c.937A>T p.I313F | Missense Mutation (SNP) | VAF 41/466 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ABCB11 | c.1524C>T p.F508= | Silent (SNP) | VAF 84/812 reads (10%) | catalogued as rs780698425; called by muse, mutect2, varscan2
- CACNA1C | c.6120C>G p.V2040= (on ENST00000399634 / NM_001167625.1; = p.V1969= on NM_000719.7) | Silent (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- CFI | c.1662G>A p.E554= | Silent (SNP) | VAF 34/667 reads (5%) | catalogued as COSV67097818; called by muse, mutect2
- HOXD4 | c.762C>T p.T254= | Silent (SNP) | VAF 27/380 reads (7%) | called by muse, mutect2
- KCNA6 | c.435C>T p.G145= | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as rs773462391, COSV54973775; called by muse, mutect2, varscan2
- KDM5D | c.2376T>G p.R792= | Silent (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- KRBA1 | c.318G>A p.A106= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs371840025; called by mutect2, varscan2
- LAMC1 | c.348C>G p.T116= | Silent (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- LMO7 | c.4116A>G p.T1372= (on ENST00000357063; = p.T1053= on NM_005358.5) | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs368110742; called by muse, mutect2
- LRP1B | c.7293C>A p.S2431= | Silent (SNP) | VAF 38/774 reads (5%) | called by muse, mutect2
- MSH5 | c.1122C>T p.I374= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs780427165, COSV65208965; called by muse, mutect2, varscan2
- MYO3A | c.228T>C p.P76= | Silent (SNP) | VAF 24/648 reads (4%) | called by muse, mutect2
- NELL1 | c.954C>A p.S318= | Silent (SNP) | VAF 69/790 reads (9%) | called by muse, mutect2
- PAPPA | c.1221C>T p.R407= | Silent (SNP) | VAF 15/327 reads (5%) | called by muse, mutect2
- PCDH15 | c.633T>C p.T211= | Silent (SNP) | VAF 65/995 reads (7%) | catalogued as rs964888718; called by muse, mutect2
- POLR1F | c.558A>T p.S186= | Silent (SNP) | VAF 78/812 reads (10%) | called by muse, mutect2
- PRR14L | c.4848A>G p.L1616= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as COSV57886190; called by muse, mutect2
- REG1B | c.222T>A p.S74= | Silent (SNP) | VAF 27/371 reads (7%) | called by muse, mutect2
- SALL3 | c.3039G>T p.G1013= | Silent (SNP) | VAF 20/528 reads (4%) | called by muse, mutect2
- SCARA5 | c.1008G>A p.G336= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs753966786; called by muse, mutect2, varscan2
- SMARCD3 | c.1338G>C p.R446= (on ENST00000262188 / NM_001003801.2; = p.R433= on NM_003078.4) | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- SOX5 | c.1107A>G p.V369= | Silent (SNP) | VAF 40/652 reads (6%) | catalogued as rs762061008; ClinVar: likely benign; called by muse, mutect2
- TNN | c.456C>A p.T152= | Silent (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- VCAN | c.6555A>T p.P2185= | Silent (SNP) | VAF 42/784 reads (5%) | called by muse, mutect2
- VWF | c.6015C>A p.I2005= | Silent (SNP) | VAF 40/476 reads (8%) | called by muse, mutect2
- ABCC8 | c.4411+26G>A | Intron (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73847652 C>G | 5'Flank (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- ALMS1P1 | chr2:73700916 G>A | 3'Flank (SNP) | VAF 48/436 reads (11%) | called by muse, mutect2, varscan2
- ARCN1 | c.3+1120A>T | Intron (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- ATP8B3 | c.678-13C>T | Intron (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 12/230 reads (5%) | catalogued as rs1291738365; called by muse, mutect2
- CHRNA1 | c.853+48T>A | Intron (SNP) | VAF 35/385 reads (9%) | called by muse, mutect2, varscan2
- DCAF17 | c.322-1195A>G | Intron (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
- HPX | c.336+54G>A | Intron (SNP) | VAF 29/372 reads (8%) | called by muse, mutect2
- KIF28P | n.2015C>A | RNA (SNP) | VAF 16/479 reads (3%) | catalogued as rs932873792; called by muse, mutect2
- N4BP2L2 | chr13:32442953 C>A | 3'Flank (SNP) | VAF 20/267 reads (7%) | catalogued as rs559227231; called by muse, mutect2
- NXF5 | n.551C>G | RNA (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- OR2W5 | n.1177C>T | RNA (SNP) | VAF 78/620 reads (13%) | called by muse, mutect2, varscan2
- RAB2A | c.186+4150C>T | Intron (SNP) | VAF 40/387 reads (10%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-148-2002A>C | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as rs1443541739; called by muse, mutect2, varscan2
- SNX27 | c.1578+110G>T | Intron (SNP) | VAF 34/472 reads (7%) | called by muse, mutect2
- SSH1 | c.111-13634G>T | Intron (SNP) | VAF 20/209 reads (10%) | called by muse, mutect2
